Somatic mutation profile of cancer-model specimen HCM-BROD-0235-C16-85B (3D Organoid, passage 4; aliquot HCM-BROD-0235-C16-85B-01D-A79C-36), derived from the metastatic tumor of HCMI case HCM-BROD-0235-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 50.7 years (18,528 days).
Specimen HCM-BROD-0235-C16-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ade4ae3e-817f-4d92-b27a-dc003cce12a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0235-C16-10B (Blood Derived Normal), aliquot HCM-BROD-0235-C16-10B-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b00fb6a0-cf7b-430e-bb81-8abe098d889f

The open-access MAF lists 55 somatic variants for this specimen: 38 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 33, Silent 17, Frame Shift Del 1, Splice Site 1, Frame Shift Ins 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCM2L | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 306/403 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs138375629; called by muse, mutect2, varscan2
- CD163 | c.1547G>T p.C516F | Missense Mutation (SNP) | VAF 101/498 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63136477; called by muse, mutect2, varscan2
- CDH1 | c.641T>C p.L214P | Missense Mutation (SNP) | VAF 356/356 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as CM065995, COSV55734778, COSV55738543, COSV55741457; called by muse, mutect2, varscan2
- DDX18 | c.914T>C p.I305T | Missense Mutation (SNP) | VAF 257/366 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as rs770462842; called by muse, mutect2, varscan2
- DDX28 | c.757C>A p.Q253K | Missense Mutation (SNP) | VAF 593/594 reads (100%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs140829287; called by muse, mutect2, varscan2
- DHRSX | c.784C>T p.L262F | Missense Mutation (SNP) | VAF 161/780 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1426778105; called by muse, mutect2, varscan2
- HYDIN | c.8236G>A p.V2746M | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV59270825; called by muse, mutect2, varscan2
- MKRN3 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 338/663 reads (51%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs781005844, COSV58808823; called by muse, mutect2, varscan2
- MMP9 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 168/890 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs371340871, COSV63433763; called by muse, mutect2, varscan2
- MUC12 | c.1523C>T p.P508L (on ENST00000379442; = p.P365L on NM_001164462.1) | Missense Mutation (SNP) | VAF 159/3193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs774154750, COSV101060102; called by muse, mutect2
- OR4A15 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 226/342 reads (66%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.192); catalogued as rs201833967; called by muse, mutect2, varscan2
- PXDN | c.1313C>T p.T438M | Missense Mutation (SNP) | VAF 230/332 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.16); catalogued as rs755575492, COSV53233112; called by muse, mutect2, varscan2
- QRFPR | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 85/164 reads (52%) | catalogued as rs767056594, COSV57676046; called by muse, mutect2, varscan2
- SPECC1L | c.2773C>T p.R925W | Missense Mutation (SNP) | VAF 125/475 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs199614545; called by muse, mutect2, varscan2
- TNNT3 | c.581G>A p.R194H (on ENST00000397301 / NM_001367846.1; = p.R183H on NM_006757.4) | Missense Mutation (SNP) | VAF 87/262 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs755730812; called by muse, mutect2, varscan2
- USP17L2 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 156/1033 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.112); catalogued as rs767583659, COSV61556104; called by muse, mutect2, varscan2
- ZNF334 | c.1915C>T p.R639C | Missense Mutation (SNP) | VAF 93/513 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as rs759953169, COSV61618453; called by muse, mutect2, varscan2
- AKAP12 | c.2722G>C p.E908Q | Missense Mutation (SNP) | VAF 124/467 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ARHGEF4 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 89/360 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ARID1A | c.3216del p.K1072Nfs*21 | Frame Shift Del (DEL) | VAF 193/267 reads (72%) | called by mutect2, pindel, varscan2
- CCDC166 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 271/761 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD1 | c.4720G>C p.G1574R (on ENST00000520002; = p.G1573R on NM_033225.6) | Missense Mutation (SNP) | VAF 93/274 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUL9 | c.6812C>T p.P2271L | Missense Mutation (SNP) | VAF 101/382 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF5B | c.284_285insC p.K96* | Frame Shift Ins (INS) | VAF 48/184 reads (26%) | called by mutect2, varscan2
- INSM2 | c.902G>A p.S301N | Missense Mutation (SNP) | VAF 406/406 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- ITGA10 | c.1792-1G>C p.X598_splice | Splice Site (SNP) | VAF 10/265 reads (4%) | called by muse, mutect2
- KNDC1 | c.1361G>A p.G454D | Missense Mutation (SNP) | VAF 141/565 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NUP58 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 91/193 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OLFM3 | c.1348G>T p.D450Y (on ENST00000338858 / NM_001288821.1; = p.D430Y on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/246 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRKCG | c.459C>G p.D153E | Missense Mutation (SNP) | VAF 30/960 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2
- PSME4 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 13/342 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); called by muse, mutect2
- TAF1 | c.667C>T p.R223C (on ENST00000373790 / NM_138923.4; = p.R244C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 237/237 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- TBC1D8 | c.1073T>C p.L358P | Missense Mutation (SNP) | VAF 83/406 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TDRD7 | c.1165A>C p.S389R | Missense Mutation (SNP) | VAF 81/248 reads (33%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- TFDP1 | c.1136C>G p.S379C | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- TP53 | c.430_435del p.Q144_L145del | In Frame Del (DEL) | VAF 333/346 reads (96%) | called by mutect2, pindel, varscan2
- TTN | c.77957A>C p.Q25986P (on ENST00000591111; = p.Q18562P on NM_003319.4) | Missense Mutation (SNP) | VAF 59/314 reads (19%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VSIR | c.583G>C p.A195P | Missense Mutation (SNP) | VAF 271/271 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ARHGEF40 | c.207A>G p.Q69= | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as rs375010957; called by muse, mutect2, varscan2
- CACNA1A | c.228G>A p.R76= | Silent (SNP) | VAF 92/2838 reads (3%) | called by muse, mutect2
- CPN2 | c.1377G>A p.P459= | Silent (SNP) | VAF 166/610 reads (27%) | catalogued as rs373278468; called by muse, mutect2, varscan2
- ESX1 | c.1092G>A p.A364= | Silent (SNP) | VAF 38/810 reads (5%) | catalogued as rs782735822; called by muse, mutect2
- HNRNPLL | c.105G>A p.S35= | Silent (SNP) | VAF 476/663 reads (72%) | called by muse, varscan2
- HS3ST4 | c.972C>T p.I324= | Silent (SNP) | VAF 114/436 reads (26%) | catalogued as rs754703038; called by muse, mutect2, varscan2
- JCAD | c.3318G>A p.A1106= | Silent (SNP) | VAF 155/615 reads (25%) | catalogued as rs781102962, COSV64757886; called by muse, mutect2, varscan2
- LRCH4 | c.789G>T p.G263= | Silent (SNP) | VAF 130/1797 reads (7%) | called by muse, mutect2
- LRRTM4 | c.345T>A p.I115= | Silent (SNP) | VAF 93/380 reads (24%) | called by muse, mutect2, varscan2
- NUFIP2 | c.1827A>G p.Q609= | Silent (SNP) | VAF 56/366 reads (15%) | catalogued as rs1446685600, COSV56604802; called by muse, mutect2, varscan2
- POLE | c.1845C>T p.S615= | Silent (SNP) | VAF 66/343 reads (19%) | catalogued as COSV57674408; called by muse, mutect2, varscan2
- RAVER1 | c.1047C>T p.P349= | Silent (SNP) | VAF 101/391 reads (26%) | called by muse, mutect2, varscan2
- SCN4A | c.4644C>T p.S1548= | Silent (SNP) | VAF 122/406 reads (30%) | catalogued as rs751973449, COSV71127890; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TFR2 | c.330G>A p.A110= | Silent (SNP) | VAF 102/1518 reads (7%) | catalogued as rs542567285; ClinVar: likely benign; called by muse, mutect2
- UHRF1BP1 | c.4308C>A p.P1436= | Silent (SNP) | VAF 46/186 reads (25%) | called by muse, mutect2, varscan2
- WASF3 | c.1419C>T p.D473= | Silent (SNP) | VAF 112/277 reads (40%) | catalogued as rs144241776; called by muse, mutect2, varscan2
- ZNF831 | c.813C>T p.S271= | Silent (SNP) | VAF 164/837 reads (20%) | catalogued as rs369672507; called by muse, mutect2, varscan2
